Gene-level copy-number profile of tumor specimen TARGET-40-PATUXZ-01A from TARGET case TARGET-40-PATUXZ, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 17.4 years (6,345 days).
Specimen TARGET-40-PATUXZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.4885ff2c-ca41-539c-9719-5e1a205820e2.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PATUXZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 370 have no estimate.
https://portal.gdc.cancer.gov/files/da893407-e902-40ed-bf4e-b904c3152dda

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 553; copy number 1: 730; copy number 2: 16,831; copy number 3: 24,058; copy number 4: 7,856; copy number 5: 3,720; copy number 6: 2,513; copy number 7: 1,754; copy number 8: 1,176; copy number 9: 373; copy number 10: 316; copy number 11: 90; copy number 12: 87; copy number 13: 25; copy number 14: 6; copy number 15: 21; copy number 16: 9; copy number 17: 3; copy number 18: 6; copy number 23: 12; copy number 24: 43; copy number 26: 7; copy number 30: 53; copy number 35: 11.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:189,764,391–190,092,279, 23 genes (within-gene range 0–2): FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr10:16,521,714–16,539,737, 1 gene: AL353576.1.
- chr14:47,764,954–47,802,201, 2 genes: LINC00648, AL121576.1.
- chr17:31,094,927–31,382,116, 1 gene (within-gene range 0–2): NF1.
- chr17:31,272,013–31,297,539, 1 gene: OMG.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,851 genes in 49 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–174,160,165, 1,103 genes, copy number 8–10 (broad region; genes not listed).
- chr4:54,221,126–57,724,655, 80 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr4:68,509,441–68,670,652, 6 genes, copy number 8: UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr4:146,052,604–146,121,913, 2 genes, copy number 10: AC108206.1, LINC01095.
- chr4:161,383,897–164,384,050, 22 genes, copy number 7 (within-gene range 3–7): FSTL5, AC023136.1, MTHFD2P4, TOMM22P4, AC021134.1, AC021134.2, AC084752.1, MIR4454, AC022272.1, NAF1, AC079238.1, NPY1R, NPY5R, RPL35AP12, TKTL2, TMA16, MARCHF1, AC093788.1, RN7SKP105, YWHAQP4, AC105250.1, ANP32C.
- chr4:165,070,608–175,019,214, 115 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr5:38,399,814–45,228,428, 113 genes, copy number 9–17 (broad region; genes not listed).
- chr7:16,087,525–18,027,846, 33 genes, copy number 7–9 (within-gene range 5–9): CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13, AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1.
- chr7:32,728,569–35,186,041, 41 genes, copy number 7–11 (within-gene range 6–11): ZNRF2P1, MIR550A2, MIR550B2, AC018645.3, LINC00997, AC018645.1, AC018645.2, DPY19L1P2, AC018648.1, KBTBD2, RP9P, AC083863.1, FKBP9, RNU6-388P, NT5C3A, RPS29P14, RN7SL505P, RP9, BBS9, AC074338.1, RNA5SP229, AC007312.1, AC006195.1, AC008080.1, AC008080.2, AC008080.4, AC008080.3, BMPER, AC007350.1, AC009262.1, RNU6-438P, NPSR1-AS1, NPSR1, RPL7P31, NCAPD2P1, RN7SL132P, AC004788.1, DPY19L1, MIR548N, AC005400.1, DPY19L2P1.
- chr8:67,043,079–68,819,023, 20 genes, copy number 7 (within-gene range 6–7): COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25.
- chr8:98,603,253–99,013,743, 10 genes, copy number 8 (within-gene range 2–8): AP003467.1, AP003467.2, RPL19P14, AC016877.2, MRPL57P7, RN7SKP85, AC016877.3, OSR2, VPS13B-DT, AC016877.1.
- chr8:109,362,461–109,565,996, 3 genes, copy number 10 (within-gene range 5–10): PKHD1L1, MAPK6P5, EBAG9.
- chr8:114,791,653–120,813,359, 59 genes, copy number 7–18: CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1, MRPL13, MTBP, SNTB1, NCAPGP1, AC104958.1, AC104958.2.
- chr8:122,781,655–125,438,403, 71 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr8:127,578,473–129,683,770, 24 genes, copy number 7–9: AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686.
- chr8:132,120,859–133,231,690, 14 genes, copy number 8–12: KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4.
- chr8:141,117,278–141,195,808, 2 genes, copy number 7: DENND3, AC040970.1.
- chr11:77,514,936–89,065,945, 173 genes, copy number 8 (within-gene range 3–28) (broad region; genes not listed).
- chr11:89,968,502–91,383,289, 34 genes, copy number 8: TRIM64, AP004607.7, TRIM51EP, TRIM53AP, AP004607.6, TRIM49C, AP004607.2, AP004607.4, TRIM64EP, AP004607.5, AP000827.1, UBTFL1, AP000648.2, AP000648.9, AP000648.1, AP000648.3, NAALAD2, AP000648.4, CHORDC1, AP002364.1, DISC1FP1, TUBAP2, MIR4490, AP002782.1, MIR1261, AP001002.3, AP001002.1, AP001002.2, OSBPL9P2, OSBPL9P3, LINC02748, AP003485.2, AP003485.1, AP002791.1.
- chr11:93,587,703–102,955,732, 142 genes, copy number 7–23 (broad region; genes not listed).
- chr11:104,682,383–108,593,768, 61 genes, copy number 9–13 (within-gene range 6–13) (broad region; genes not listed).
- chr11:109,637,468–111,040,208, 16 genes, copy number 8: AP003102.1, LINC02715, RDX, TFAMP2, AP001981.2, RPSAP50, AP001981.1, AP001889.1, ZC3H12C, LINC02732, FDX1, ARHGAP20, HNRNPA1P60, AP002963.1, AP003973.4, RNA5SP350.
- chr11:115,659,658–116,658,295, 10 genes, copy number 8 (within-gene range 5–8): LINC02698, AP002991.1, AP002991.2, LINC00900, LINC02703, AP000797.2, AP000797.1, LINC02151, AP000770.1, LINC02702.
- chr11:121,292,681–121,633,763, 5 genes, copy number 8 (within-gene range 5–8): SC5D, BMPR1AP2, AP002365.1, AP000977.1, SORL1.
- chr11:134,069,071–134,225,454, 5 genes, copy number 9: JAM3, PTP4A2P2, NCAPD3, AP001775.1, AP001775.2.
- chr13:83,650,249–94,803,430, 108 genes, copy number 7–9 (broad region; genes not listed).
- chr13:97,939,356–114,337,626, 268 genes, copy number 7 (broad region; genes not listed).
- chr14:20,870,278–20,936,255, 4 genes, copy number 8 (within-gene range 3–8): AL133371.3, AL133371.1, RNASE3, AL355922.4.
- chr14:87,634,379–88,159,845, 11 genes, copy number 8 (within-gene range 6–10): LINC02330, AL359237.1, AL136501.1, GALC, SHLD2P2, RNU6-835P, GPR65, AL157955.1, LINC01147, LINC01146, AL133279.2.
- chr14:93,397,139–93,437,510, 2 genes, copy number 8: Y_RNA, RNU6-1258P.
- chr15:93,301,416–94,107,938, 11 genes, copy number 7 (within-gene range 6–7): AC112693.2, AC091078.2, SEPHS1P2, AC110023.1, LINC01579, AC103996.1, LINC02207, AC103996.3, AC103996.2, LINC01580, LINC01581.
- chr17:10,383,132–15,793,045, 117 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr17:61,034,636–83,095,122, 719 genes, copy number 7 (broad region; genes not listed).
- chr18:9,102,630–12,040,300, 83 genes, copy number 7 (broad region; genes not listed).
- chr20:3,465,177–4,249,287, 27 genes, copy number 7: AL353193.1, ATRN, SF3A3P1, GFRA4, ADAM33, SIGLEC1, HSPA12B, C20orf27, SPEF1, CENPB, CDC25B, LINC01730, AL109804.1, AP5S1, MAVS, PANK2-AS1, PANK2, MIR103A2, MIR103B2, AL031670.1, RNF24, FTLP3, RPL21P2, AL356414.1, SMOX, LINC01433, ADRA1D.
- chr20:5,013,520–11,687,323, 105 genes, copy number 7–14 (within-gene range 4–14) (broad region; genes not listed).
- chr20:23,547,764–24,446,314, 25 genes, copy number 7: CST9LP1, CST9L, CST9LP2, CST9, CST3, AL121894.2, AL121894.1, AL121894.3, CST4, CST2P1, AL591074.2, CST1, CSTP2, AL591074.1, CST2, CST5, CSTP1, AL133466.1, GGTLC1, POM121L3P, LINC01721, AL110503.1, RNU1-23P, AL158090.1, GAPDHP53.
- chr22:18,178,038–20,495,844, 124 genes, copy number 7–10 (within-gene range 1–10) (broad region; genes not listed).
- chr22:37,876,148–38,872,249, 55 genes, copy number 8: AL022311.1, RNU6-900P, MICALL1, AL031587.5, C22orf23, AL031587.3, POLR2F, MIR6820, SOX10, MIR4534, AL031587.1, AL031587.4, PICK1, AL031587.2, SLC16A8, BAIAP2L2, AL022322.1, PLA2G6, AL022322.2, MAFF, TMEM184B, AL020993.1, RN7SL704P, Metazoa_SRP, CSNK1E, TPTEP2-CSNK1E, TPTEP2, Z98749.1, Z97056.2, Z97056.1, KCNJ4, Z97056.3, KDELR3, DDX17, DMC1, RPS29P31, FAM227A, CBY1, AL021707.4, AL021707.2, AL021707.9, TOMM22, JOSD1, GTPBP1, PRDX3P1, AL021707.5, SUN2, AL021707.3, AL021707.8, AL021707.1, AL021707.6, AL021707.7, DNAL4, NPTXR, CBX6.
- chr22:39,570,753–40,636,719, 19 genes, copy number 7 (within-gene range 4–7): CACNA1I, ENTHD1, MTFR2P2, RN7SKP210, UQCRFS1P1, GRAP2, Z82206.1, FAM83F, Z83847.1, TNRC6B, RPL7P52, ADSL, AL022238.3, SGSM3, SGSM3-AS1, MRTFA, AL022238.2, AL022238.1, MRTFA-AS1.

Autosomal genes at a single copy (total copy number 1): 729. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
